Somatic mutation profile of tumor specimen RC-B667-TBP1-B (aliquot RC-B667-TBP1-B-1-0-D-A93N-47) from RC case RC-B667, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: T-cell large granular lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 33.6 years (12,255 days).
Specimen RC-B667-TBP1-B: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 267be37b-56a4-40ab-97f9-bde16439a810.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B667-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B667-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54b48530-25ea-4850-8bdb-8b18b8402ae3

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Ins 2, Splice Region 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL8A1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113865999; called by muse, mutect2, varscan2
- CSMD1 | c.5137C>A p.L1713M (on ENST00000520002; = p.L1712M on NM_033225.6) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as COSV59340382; called by mutect2, varscan2
- GLI2 | c.3341T>C p.F1114S (on ENST00000361492 / NM_001374353.1; = p.F1131S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1215796726; called by muse, mutect2
- GREB1 | c.3805G>A p.V1269I | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1244751361; called by muse, mutect2, varscan2
- NAV3 | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 17/226 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs770984486, COSV57085751; called by muse, mutect2
- ANKRD30B | c.3554C>A p.A1185D | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- HDAC5 | c.3081G>A p.L1027= | Splice Region (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- KIF26A | c.3878C>A p.A1293E | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MCPH1 | c.1484C>A p.T495N | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.568); called by muse, mutect2
- MUC19 | n.19048C>A | Splice Region (SNP) | VAF 30/153 reads (20%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.2018A>G p.D673G | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- SETD1B | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- SPDEF | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM49 | c.441G>T p.L147F | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, varscan2
- WDFY4 | c.1495C>T p.L499F | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); called by muse, varscan2
- ZFP42 | c.787dup p.R263Pfs*29 | Frame Shift Ins (INS) | VAF 34/141 reads (24%) | called by mutect2, varscan2
- ZFP42 | c.788delinsCC p.R263Pfs*29 | Frame Shift Ins (INS) | VAF 36/178 reads (20%) | called by mutect2*, pindel, varscan2*
- ZNF655 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.012); called by muse, mutect2
- FLT4 | c.1980C>T p.S660= | Silent (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- GRHL2 | c.618C>T p.D206= | Silent (SNP) | VAF 30/180 reads (17%) | catalogued as rs773025507, COSV52550435; called by muse, mutect2, varscan2
- KIAA2013 | c.816C>T p.R272= | Silent (SNP) | VAF 15/344 reads (4%) | called by muse, mutect2
- SI | c.447A>T p.T149= | Silent (SNP) | VAF 33/151 reads (22%) | called by muse, mutect2, varscan2
- SPAAR | c.213C>T p.F71= | Silent (SNP) | VAF 25/142 reads (18%) | called by muse, mutect2, varscan2
- SOHLH1 | c.*576G>A | 3'UTR (SNP) | VAF 43/149 reads (29%) | called by muse, mutect2, varscan2
